Somatic mutation profile of tumor specimen C3L-02364-01 (aliquot CPT0113260009) from CPTAC case C3L-02364, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 56.7 years (20,720 days).
Specimen C3L-02364-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 917a8bd0-7c67-4341-ae78-770ba1caa517.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-02364-31 (Blood Derived Normal), aliquot CPT0115270002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b3d816f2-faf3-475d-abb7-633eb5680453

The open-access MAF lists 24 somatic variants for this specimen: 16 protein-altering or splice-affecting, 4 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 4, Nonsense Mutation 2, 5'UTR 2, Intron 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FAT3 | c.13582G>A p.V4528I | Missense Mutation (SNP) | VAF 32/467 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs1454511112; called by muse, mutect2
- GALC | c.251A>T p.D84V | Missense Mutation (SNP) | VAF 17/146 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM162959; called by muse, mutect2, varscan2
- MUC16 | c.956C>T p.A319V | Missense Mutation (SNP) | VAF 13/162 reads (8%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0); catalogued as rs751586070; called by muse, mutect2
- TBC1D1 | c.1906C>T p.R636* | Nonsense Mutation (SNP) | VAF 5/83 reads (6%) | catalogued as rs1234254986; called by muse, mutect2
- VPS13D | c.12901G>A p.E4301K | Missense Mutation (SNP) | VAF 18/244 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.257); catalogued as COSV50638022; called by muse, mutect2
- ADGRG4 | c.7688G>T p.G2563V | Missense Mutation (SNP) | VAF 18/93 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.157); called by muse, mutect2, varscan2
- ATRX | c.2136G>T p.K712N | Missense Mutation (SNP) | VAF 10/97 reads (10%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ATRX | c.2135A>T p.K712M | Missense Mutation (SNP) | VAF 10/97 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- HAO1 | c.484C>G p.P162A | Missense Mutation (SNP) | VAF 18/307 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.609); called by muse, mutect2
- IGKV1-12 | c.65G>T p.C22F | Missense Mutation (SNP) | VAF 22/602 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.056); called by muse, mutect2
- MUC22 | c.4732G>A p.D1578N | Missense Mutation (SNP) | VAF 16/168 reads (10%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.937); called by muse, mutect2
- RASAL3 | c.134G>A p.G45D | Missense Mutation (SNP) | VAF 18/244 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.29); called by muse, mutect2
- RORC | c.987G>T p.Q329H | Missense Mutation (SNP) | VAF 15/256 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.87); called by muse, mutect2
- SFPQ | c.1204G>T p.V402L | Missense Mutation (SNP) | VAF 24/298 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.493); called by muse, mutect2
- USP32 | c.1579C>T p.Q527* | Nonsense Mutation (SNP) | VAF 10/246 reads (4%) | called by muse, mutect2
- ZC3H3 | c.600del p.M201Wfs*2 | Frame Shift Del (DEL) | VAF 23/235 reads (10%) | called by mutect2, pindel, varscan2
- ABCC2 | c.3267C>A p.S1089= | Silent (SNP) | VAF 26/355 reads (7%) | called by muse, mutect2
- ELOVL6 | c.171T>C p.F57= | Silent (SNP) | VAF 9/209 reads (4%) | called by muse, mutect2
- MT2A | c.81C>G p.T27= | Silent (SNP) | VAF 13/338 reads (4%) | called by muse, mutect2
- SNX14 | c.18G>C p.R6= | Silent (SNP) | VAF 22/357 reads (6%) | called by muse, mutect2
- DNMT3B | c.-29C>A | 5'UTR (SNP) | VAF 3/48 reads (6%) | called by muse, mutect2
- MYOCD | c.2059-1562A>G | Intron (SNP) | VAF 8/166 reads (5%) | called by muse, mutect2
- SCAF8 | c.-388del | 5'UTR (DEL) | VAF 5/32 reads (16%) | called by mutect2, pindel, varscan2
- SYTL2 | c.1459+213G>C | Intron (SNP) | VAF 11/88 reads (13%) | called by muse, mutect2, varscan2
